Somatic mutation profile of tumor specimen TCGA-UF-A7JJ-01A (aliquot TCGA-UF-A7JJ-01A-11D-A34J-08) from TCGA case TCGA-UF-A7JJ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 69.0 years (25,201 days).
Specimen TCGA-UF-A7JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71284634-4fd4-4ccc-9848-93ecabf3dac5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JJ-10A (Blood Derived Normal), aliquot TCGA-UF-A7JJ-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/829ea21f-4495-4fc6-9169-ab87d5087470

The open-access MAF lists 74 somatic variants for this specimen: 61 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 54, Silent 13, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.216dup p.V73Rfs*76 | Frame Shift Ins (INS) | VAF 37/213 reads (17%) | catalogued as rs730882018, COSV104369723; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ACKR1 | c.469C>A p.L157M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.977); catalogued as COSV100929520; called by muse, mutect2
- ADAMTS14 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs1367833419, COSV100941497; called by muse, mutect2, varscan2
- ADCY8 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs766740204, COSV53922340, COSV99651651; called by muse, mutect2, varscan2
- AK5 | c.436G>A p.G146S (on ENST00000354567 / NM_174858.3; = p.G120S on NM_012093.4) | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100481425, COSV58356919; called by muse, mutect2
- ANO7 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as COSV99238022; called by muse, mutect2
- APC | c.3356A>G p.H1119R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.193); catalogued as COSV99967043; called by muse, mutect2
- ARHGAP4 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100603986; called by muse, mutect2, varscan2
- ARSK | c.1423A>C p.K475Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1325581804, COSV101187536; called by muse, mutect2, varscan2
- CNTNAP4 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1438428167, COSV100270627; called by muse, mutect2
- COL1A2 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs67031201, CM070803, CM962605, COSV99799287; called by muse, mutect2
- CREBBP | c.5452G>T p.V1818L | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.675); catalogued as COSV52131330, COSV99269460; called by muse, mutect2
- CUL1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as COSV100296579; called by muse, mutect2, varscan2
- DTX3 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99677817; called by muse, mutect2
- EIF5A | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV59748478; called by muse, mutect2, varscan2
- EPB41L3 | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 6/124 reads (5%) | catalogued as COSV100548681; called by muse, mutect2
- EXOC6 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV99591725; called by muse, mutect2, varscan2
- FAT4 | c.10087C>A p.L3363I | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58671994, COSV58678908; called by muse, mutect2
- FNIP1 | c.3172A>T p.T1058S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.12); catalogued as COSV100330374; called by muse, mutect2
- FNIP1 | c.3170G>T p.W1057L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100330375; called by muse, mutect2
- FPGT | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63835221; called by muse, mutect2
- GP2 | c.1426-1G>T p.X476_splice (on ENST00000381362 / NM_001007240.3; = p.X473_splice on NM_001502.4) | Splice Site (SNP) | VAF 8/95 reads (8%) | catalogued as COSV100221391; called by muse, mutect2
- HLA-A | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs746490000, COSV100954348; called by muse, mutect2, varscan2
- HNRNPA3 | c.986A>C p.Y329S | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.591); catalogued as COSV101182893; called by muse, mutect2, varscan2
- ITGBL1 | c.320A>T p.H107L | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV101095244, COSV66012561; called by muse, mutect2
- LRP1 | c.10988A>G p.N3663S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99675444; called by muse, mutect2, varscan2
- LRP1B | c.6387C>A p.N2129K | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV101255248; called by muse, mutect2
- LTBP4 | c.4460A>T p.E1487V (on ENST00000308370 / NM_001042544.1; = p.E1450V on NM_003573.2) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV99184881; called by muse, mutect2, varscan2
- MCL1 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100329510, COSV57190396; called by muse, mutect2
- MEX3A | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV101348925; called by muse, mutect2, varscan2
- MGAT4C | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152837, COSV59832892; called by muse, mutect2
- MYO7A | c.2977G>C p.E993Q | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.602); catalogued as COSV101289097; called by muse, mutect2, varscan2
- NOBOX | c.502C>A p.H168N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.366); catalogued as COSV99779364; called by muse, mutect2
- NR2F2 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101240991; called by muse, mutect2, varscan2
- NTRK3 | c.2185C>A p.H729N (on ENST00000360948 / NM_001012338.2; = p.H715N on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV62301086, COSV62306579; called by muse, mutect2
- NUP205 | c.5504A>T p.Q1835L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99606798; called by muse, mutect2, varscan2
- OR2D3 | c.239G>C p.R80T | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV58573478, COSV58574064; called by muse, mutect2
- OR52D1 | c.29A>G p.H10R | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100495204; called by muse, mutect2, varscan2
- PABPC1 | c.1522G>T p.V508F | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.105); catalogued as COSV100589479, COSV59407169; called by muse, mutect2
- PITPNM3 | c.61C>G p.R21G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99338217; called by muse, mutect2, varscan2
- PRDM9 | c.119G>T p.W40L | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99690238; called by muse, mutect2
- RAB12 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV100251504; called by muse, mutect2
- SATL1 | c.94A>T p.S32C (on ENST00000395409; = p.S219C on NM_001012980.2) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV100260767; called by muse, mutect2, varscan2
- SESTD1 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100090382; called by muse, mutect2
- SHC4 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs1333778336, COSV100194394; called by muse, mutect2
- SIAE | c.1323C>G p.I441M | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99422346; called by muse, mutect2, varscan2
- SLC13A1 | c.1718T>A p.I573N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs536599511, COSV99520725; called by muse, mutect2, varscan2
- SLC25A2 | c.308A>C p.K103T | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV99508217; called by muse, mutect2
- SLC25A32 | c.297C>A p.Y99* | Nonsense Mutation (SNP) | VAF 19/212 reads (9%) | catalogued as COSV99884358; called by muse, mutect2
- SPANXN2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 54/458 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.861); catalogued as COSV65128307; called by muse, varscan2
- SPATA7 | c.544A>G p.S182G | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV99247879; called by muse, mutect2, varscan2
- STX5 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180401938, COSV53682534; called by muse, mutect2, varscan2
- TARS1 | c.1276T>C p.S426P | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99465800; called by muse, mutect2
- TCEAL2 | c.128A>G p.N43S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.79); catalogued as COSV100216281; called by muse, mutect2
- TDRD5 | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99675962; called by muse, mutect2
- UBR4 | c.13801A>G p.I4601V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.833); catalogued as COSV100920677; called by muse, mutect2, varscan2
- XIRP2 | c.5000C>A p.T1667K (on ENST00000628543; = p.T1842K on NM_152381.6) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99741373; called by muse, mutect2, varscan2
- ZNF611 | c.1379A>T p.D460V | Missense Mutation (SNP) | VAF 54/355 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100160187; called by muse, mutect2, varscan2
- FAT1 | c.5544_5565del p.Q1848Hfs*11 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- MYH9 | c.4326del p.K1442Nfs*69 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel*, varscan2
- NCAM1 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- CNTN5 | c.2070C>A p.S690= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs1226898980, COSV99675458; called by muse, mutect2, varscan2
- CRY2 | c.402G>A p.K134= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV101314573; called by muse, mutect2
- CSMD1 | c.3252T>C p.L1084= (on ENST00000520002; = p.L1083= on NM_033225.6) | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs374597074; called by muse, mutect2, varscan2
- LGI2 | c.1269G>A p.V423= | Silent (SNP) | VAF 28/502 reads (6%) | catalogued as COSV101180804; called by muse, mutect2
- LRRIQ4 | c.372G>A p.R124= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100540185; called by muse, mutect2, varscan2
- MYNN | c.420A>G p.Q140= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV100581937; called by muse, mutect2
- REG1A | c.489G>A p.K163= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as rs1408778793, COSV99286751; called by muse, mutect2
- RREB1 | c.1905G>A p.T635= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs780891478, COSV100619276; called by muse, mutect2, varscan2
- SON | c.651A>G p.V217= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV99277722; called by muse, mutect2
- TRIM48 | c.633A>C p.A211= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV101338252; called by muse, mutect2
- TUBA3C | c.690G>C p.L230= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as COSV101262778; called by muse, mutect2
- UBD | c.201C>A p.G67= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100589602; called by muse, mutect2, varscan2
- ZNF423 | c.1216C>A p.R406= (on ENST00000563137 / NM_001379286.1; = p.R398= on NM_015069.4) | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs368847069, COSV99281009; called by muse, mutect2
